Somatic mutation profile of tumor specimen TCGA-EM-A1YD-01A (aliquot TCGA-EM-A1YD-01A-11D-A14W-08) from TCGA case TCGA-EM-A1YD, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 53.0 years (19,366 days).
Specimen TCGA-EM-A1YD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8040172a-d6bb-4005-9268-fe3652635625.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A1YD-11A (Solid Tissue Normal), aliquot TCGA-EM-A1YD-11A-11D-A14W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/44249e45-b011-493d-90ce-19f69b12f00e

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASMT | c.251A>G p.Y84C | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); catalogued as rs767931039, COSV67109635; called by muse, mutect2, varscan2
- PTPRT | c.1012C>T p.H338Y | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV61966956; called by muse, mutect2, varscan2
- SKAP2 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1244594951, COSV61722008, COSV61726565; called by muse, mutect2, varscan2
- WT1 | c.1293G>T p.R431S | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.626); catalogued as COSV60068010, COSV60071892; called by muse, mutect2
- KRT79 | c.615G>A p.T205= | Silent (SNP) | VAF 24/115 reads (21%) | catalogued as rs200800580, COSV57938891; called by muse, mutect2, varscan2
- ZFP42 | c.129C>T p.V43= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as COSV58816676; called by muse, mutect2, varscan2
